Somatic mutation profile of tumor specimen 0DBQFE from CCDI case PBBLPR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.0 years (4,007 days).
Specimen 0DBQFE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36c777f7-e865-4685-8d0f-958daf0a2786.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBQFA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88fca88c-c2f3-4e0a-96a9-6e9aa2c95aeb

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCH1 | c.114dup p.L39Afs*51 | Frame Shift Ins (INS) | VAF 85/206 reads (41%) | catalogued as rs751977093; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SALL4 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 175/381 reads (46%) | catalogued as rs1057521145, CM042109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 215/380 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- BEND4 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 201/401 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1560574798, COSV72469127; called by muse, mutect2, varscan2
- C5orf63 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 213/519 reads (41%) | SIFT deleterious, low confidence (0); catalogued as rs534484470, COSV56986067; called by muse, mutect2, varscan2
- C8G | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 154/361 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs747699740; called by muse, mutect2, varscan2
- DDX3X | c.1048C>T p.R350W (on ENST00000399959; = p.R351W on NM_001356.5) | Missense Mutation (SNP) | VAF 251/565 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67864267; called by muse, mutect2, varscan2
- PNMA6E | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 267/550 reads (49%) | SIFT tolerated (0.05); catalogued as rs1556970862; called by muse, mutect2, varscan2
- PTCH1 | c.387G>A p.W129* | Nonsense Mutation (SNP) | VAF 140/327 reads (43%) | catalogued as CM127601, COSV59494824; called by muse, mutect2, varscan2
- ZNF100 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs746055850; called by muse, mutect2, varscan2
- ZNF836 | c.2419G>A p.V807M | Missense Mutation (SNP) | VAF 188/431 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs147651458, COSV100441187, COSV59082918; called by muse, mutect2, varscan2
- CDC27 | c.1675_1676del p.L559Nfs*5 | Frame Shift Del (DEL) | VAF 182/420 reads (43%) | called by mutect2, varscan2
- NUP160 | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 246/533 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PRSS22 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RIMS1 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 222/245 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RLIM | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 210/592 reads (35%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHISAL1 | c.370A>T p.N124Y | Missense Mutation (SNP) | VAF 300/687 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKAP2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 222/544 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.227); called by muse, varscan2
- ZNF888 | c.1316A>T p.K439M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- BEND6 | c.213C>T p.C71= | Silent (SNP) | VAF 374/425 reads (88%) | catalogued as rs377361378; called by muse, mutect2, varscan2
- GCDH | c.834T>A p.P278= | Silent (SNP) | VAF 242/474 reads (51%) | called by muse, mutect2, varscan2
- HCAR2 | c.1047C>T p.S349= | Silent (SNP) | VAF 109/763 reads (14%) | catalogued as rs758328375; called by muse, varscan2
- HCAR3 | c.1047C>T p.S349= | Silent (SNP) | VAF 162/413 reads (39%) | catalogued as rs768127646; called by muse, mutect2, varscan2
- MAGEA3 | c.183T>C p.P61= | Silent (SNP) | VAF 67/208 reads (32%) | catalogued as rs782704569; called by muse, mutect2, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- MAGEC3 | c.1728+18G>T | Intron (SNP) | VAF 181/370 reads (49%) | called by muse, varscan2
- PDHA1 | c.-68C>G | 5'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
